Surgical pathology report (de-identified scan), TCGA case TCGA-HP-A5N0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HP-A5N0-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Hepatocellular carcinoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	Resection
Site of Tissue/Primary (Histology)	hepatic, biliary tree - liver
Tumour Size (cm)	N/A
Histology	hepatocellular carcinoma, clear cell variant 90% per email (altered)
Grade/Differentiation	X
Pathological T	TX
Pathological N	NX
Clinical M	M1
Histology Comments	Liver - Tumour Content - 100% - cause of death - CHF; patient has recurrent lesions that are slow growing

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3
Carcinoma, hepatocellular, Clear Cell Type
8174/3

Site: Liver, hepatic 022.0
9/0 4/4/13

OK to process, per NCI and BWG.
BCE

4/2/13 "ON HOLD"

Diagnosis Discrepancy	clear cell	

TSS #2310

(RB)

Source: NCI Genomic Data Commons file 318879b5-e6c7-4459-85c5-edcd06b9e4e7 (TCGA-HP-A5N0.0221A6F3-34F5-407E-8548-B62F27F66FCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).